Somatic mutation profile of tumor specimen MP2PRT-PAVUEM-TMP1-A (aliquot MP2PRT-PAVUEM-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVUEM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 9.7 years (3,556 days).
Specimen MP2PRT-PAVUEM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03e6c6ee-972a-4587-9b0c-0b9ecffff491.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUEM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUEM-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b7ce7ab-5de2-4b44-bec1-e2717c7daad1

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASL | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199938613, CM141220, COSV100508883; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 32/362 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAM2 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55859210; called by muse, mutect2
- CRISP2 | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 40/194 reads (21%) | catalogued as rs147611117; called by muse, mutect2, varscan2
- DOCK11 | c.2819C>T p.T940M | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as rs1051293197; called by muse, mutect2, varscan2
- ISX | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 59/398 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs373068000; called by muse, mutect2, varscan2
- RADIL | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 112/493 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101271300, COSV101271529; called by muse, mutect2, varscan2
- CHFR | c.1283G>A p.C428Y (on ENST00000432561 / NM_001161345.1; = p.C387Y on NM_018223.2) | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- EFR3B | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- KBTBD6 | c.1961_1962insGGGGAGACCC p.E655Gfs*4 | Frame Shift Ins (INS) | VAF 76/274 reads (28%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.664_665del p.G222Sfs*79 | Frame Shift Del (DEL) | VAF 30/382 reads (8%) | called by mutect2, pindel*
- WDR7 | c.3527G>T p.C1176F | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- FBXO24 | c.402C>T p.H134= (on ENST00000241071 / NM_033506.3; = p.H172= on NM_012172.5) | Silent (SNP) | VAF 94/454 reads (21%) | catalogued as rs766451108, COSV53825075; called by muse, mutect2, varscan2
- GRM5 | c.1911G>T p.A637= | Silent (SNP) | VAF 50/335 reads (15%) | called by muse, mutect2, varscan2
- IP6K3 | c.357C>T p.S119= | Silent (SNP) | VAF 211/722 reads (29%) | catalogued as rs753519496, COSV53389720; called by muse, mutect2, varscan2
- IQSEC3 | c.3453G>A p.P1151= | Silent (SNP) | VAF 82/357 reads (23%) | catalogued as rs772195465, COSV58286446; called by muse, mutect2
- POTEJ | c.2511C>T p.A837= | Silent (SNP) | VAF 46/393 reads (12%) | catalogued as rs199885708; called by muse, mutect2, varscan2
- SCN9A | c.1875C>T p.N625= | Silent (SNP) | VAF 112/426 reads (26%) | catalogued as rs1168052072, COSV57604510; called by muse, mutect2, varscan2
